Somatic mutation profile of tumor specimen 0DSF01 from CCDI case PBCHYB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.2 years (2,639 days).
Specimen 0DSF01: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5027fed6-4165-4713-907d-0460b390d969.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSEYZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9868395-77b8-4e90-9108-f2a7333b2c96

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Splice Site 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1H | c.6199G>A p.V2067I | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs370883583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP2C19 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 141/326 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs192154563, CM116501, COSV64907194; ClinVar: drug response; called by muse, mutect2, varscan2
- EIF3A | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 277/571 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64960996; called by muse, mutect2, varscan2
- GJA8 | c.134G>T p.W45L | Missense Mutation (SNP) | VAF 164/458 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM080380; called by muse, mutect2, varscan2
- SCN1A | c.5822C>T p.T1941M (on ENST00000303395 / NM_001202435.3; = p.T1930M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 240/523 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.075); catalogued as rs756845310, COSV57660387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VSX1 | c.627+1G>T p.X209_splice | Splice Site (SNP) | VAF 195/443 reads (44%) | catalogued as COSV65022136; called by muse, mutect2, varscan2
- PLCZ1 | c.559G>C p.G187R | Missense Mutation (SNP) | VAF 135/314 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMARCA4 | c.4170+2T>C p.X1390_splice | Splice Site (SNP) | VAF 123/285 reads (43%) | called by muse, mutect2, varscan2
- ULBP1 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 186/387 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POU3F3 | c.-71C>T | 5'UTR (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- SLC19A1 | c.190-2555C>A | Intron (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
